Somatic mutation profile of tumor specimen TCGA-S9-A6UB-01A (aliquot TCGA-S9-A6UB-01A-21D-A33T-08) from TCGA case TCGA-S9-A6UB, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 52.6 years (19,223 days).
Specimen TCGA-S9-A6UB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51144d26-d23e-4dff-9da8-25780dbc05b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6UB-10A (Blood Derived Normal), aliquot TCGA-S9-A6UB-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f064a271-82f8-4db3-82ae-981b03441626

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 14, Silent 9, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 79/194 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ASF1B | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV99654187; called by muse, mutect2
- CDC73 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs1060500011, COSV100813655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP251 | c.2374C>G p.Q792E | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99995567; called by muse, mutect2, varscan2
- CIC | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as COSV99358657; called by muse, mutect2, varscan2
- FAT3 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 129/325 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV53183712, COSV99959488; called by muse, mutect2, varscan2
- HASPIN | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.166); catalogued as COSV99560041; called by muse, mutect2, varscan2
- MSLN | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs759331194, COSV53499513; called by muse, mutect2, varscan2
- NIPBL | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 189/469 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV99238092; called by muse, mutect2, varscan2
- OR10G4 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100304631; called by muse, mutect2, varscan2
- PCDHA1 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100974224; called by muse, mutect2, varscan2
- PFKP | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11542782, COSV101126810; called by muse, mutect2
- SSX5 | c.229G>A p.A77T (on ENST00000347757 / NM_175723.1; = p.A118T on NM_021015.4) | Missense Mutation (SNP) | VAF 151/177 reads (85%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs200600341, COSV61255302, COSV61255941; called by muse, mutect2, varscan2
- TRAF5 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99807152; called by muse, mutect2, varscan2
- U2AF2 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58275041; called by muse, mutect2, varscan2
- GPR149 | c.678_682del p.H226Qfs*59 | Frame Shift Del (DEL) | VAF 47/139 reads (34%) | called by pindel, varscan2
- KIAA1586 | c.1682dup p.R562Kfs*14 | Frame Shift Ins (INS) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- DHX34 | c.2943C>T p.A981= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100169087; called by muse, mutect2
- ENTPD1 | c.138C>T p.N46= | Silent (SNP) | VAF 68/142 reads (48%) | catalogued as rs1217512827, COSV100967328; called by muse, mutect2, varscan2
- GPR83 | c.954G>A p.K318= | Silent (SNP) | VAF 9/222 reads (4%) | catalogued as COSV99703481; called by muse, mutect2
- HIVEP1 | c.3489G>A p.Q1163= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV101044350, COSV101044452; called by muse, mutect2, varscan2
- OR13F1 | c.387C>T p.P129= | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as COSV100594655; called by muse, mutect2, varscan2
- PHRF1 | c.366G>A p.T122= | Silent (SNP) | VAF 69/200 reads (35%) | catalogued as rs756838361, COSV99199331; called by muse, mutect2
- RGS6 | c.24A>G p.Q8= | Silent (SNP) | VAF 56/150 reads (37%) | catalogued as COSV100664497; called by muse, mutect2, varscan2
- SLC16A3 | c.708G>A p.S236= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs745813922, COSV101125872; called by muse, mutect2
- ZNF366 | c.1215G>A p.P405= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as rs753375178, COSV100573985; called by muse, mutect2, varscan2
